Somatic mutation profile of tumor specimen MP2PRT-PAWAZE-TMP1-A (aliquot MP2PRT-PAWAZE-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAWAZE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.4 years (3,050 days).
Specimen MP2PRT-PAWAZE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8b19dd16-17d3-4b47-a4a0-200b4a1cbe6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWAZE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWAZE-NB1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e6bd072-9547-44e1-b1af-45fcd765b6e6

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 2, Frame Shift Ins 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL6A2 | c.1004A>G p.K335R | Missense Mutation (SNP) | VAF 130/259 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.306); catalogued as rs749917539; called by muse, mutect2, varscan2
- FABP6 | c.50A>G p.Q17R | Missense Mutation (SNP) | VAF 15/315 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101221154; called by muse, mutect2
- FAM83H | c.1106C>T p.P369L | Missense Mutation (SNP) | VAF 273/576 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs1273372287, COSV66353622; called by muse, mutect2, varscan2
- KLHL30 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 217/433 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779828832; called by muse, mutect2, varscan2
- LRRC8E | c.1042C>T p.R348W | Missense Mutation (SNP) | VAF 122/305 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773852896, COSV100142858; called by muse, mutect2, varscan2
- CSN2 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 189/429 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- GABRB2 | c.567G>C p.E189D | Missense Mutation (SNP) | VAF 90/183 reads (49%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- GCKR | c.1291A>C p.N431H | Missense Mutation (SNP) | VAF 14/314 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.012); called by muse, mutect2
- GTF3C3 | c.688dup p.Q230Pfs*5 | Frame Shift Ins (INS) | VAF 113/294 reads (38%) | called by mutect2, pindel, varscan2
- MBD2 | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 218/498 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- NCOR1 | c.5854del p.S1952Lfs*24 | Frame Shift Del (DEL) | VAF 45/129 reads (35%) | called by pindel*, varscan2
- PDPR | c.62A>G p.N21S | Missense Mutation (SNP) | VAF 101/368 reads (27%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNPR | c.479A>C p.Q160P | Missense Mutation (SNP) | VAF 128/284 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- VAX1 | c.806G>A p.G269D | Missense Mutation (SNP) | VAF 237/644 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EPB41L3 | c.2490G>A p.T830= | Silent (SNP) | VAF 61/146 reads (42%) | catalogued as rs747043897, COSV59469707; called by muse, mutect2, varscan2
- TAS2R4 | c.693G>A p.L231= | Silent (SNP) | VAF 140/310 reads (45%) | called by muse, mutect2, varscan2
- TRPM3 | c.184-256700C>T | Intron (SNP) | VAF 145/303 reads (48%) | catalogued as rs371498948; called by muse, mutect2, varscan2
